MMRF case MMRF_1687 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/aa03e560-54cd-4929-a290-e126dfaac8dc

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 211 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 77.8 years (28,409 days); ISS stage: I; Days to last known disease status: 211 days; Days to last follow up: 211 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 114 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 146 days; Days to treatment end: 177 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 211.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -36 (ECOG 0): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 788 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 9.85 g/L; Immunoglobulin A 1.3 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 10.6 ×10⁹/L; Absolute Neutrophil 7.8 ×10⁹/L; Platelets 292 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.05 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L; C-Reactive Protein 3.61 mg/dL.
- Day 71 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 234 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.97 mg/dL; Hemoglobin 6.88 mmol/L; Leukocytes 5.34 ×10⁹/L; Absolute Neutrophil 4.12 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 7.3 g/dL; Glucose 6.55 mmol/L.
- Day 153 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 42.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.29 mg/dL; Immunoglobulin G 8.17 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 8.64 ×10⁹/L; Absolute Neutrophil 6.74 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 4.68 mmol/L.

Other clinical attributes
- Day -36: Weight: 62 kg; Height: 165 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1687_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -36 days.
- Sample MMRF_1687_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -36 days.
